Gene-level copy-number profile of tumor specimen MP2PRT-PATZNC-TMP1-A from MP2PRT case MP2PRT-PATZNC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.6 years (1,316 days).
Specimen MP2PRT-PATZNC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 819442f2-6d68-415e-a87c-c1456ed97f36.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PATZNC-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/fc5c3fd7-5b3e-4c9f-99ea-663f8b95f96a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 53; copy number 1: 3,672; copy number 2: 53,682; copy number 3: 1,490; copy number 8: 4.

Homozygous deletions (total copy number 0; autosomes only): 53 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,085,177–89,085,787, 1 gene (within-gene range 0–1): IGKV3-15.
- chr2:89,221,698–89,252,736, 4 genes (within-gene range 0–1): IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31.
- chr2:89,968,867–90,005,629, 4 genes: IGKV1D-27, IGKV2D-26, IGKV3D-25, IGKV2D-24.
- chr7:38,239,580–38,340,998, 16 genes (within-gene range 0–2): TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,354,517, 3 genes (within-gene range 0–2): TRGV5P, TRGV5, TRGV4.
- chr9:21,201,469–21,209,779, 3 genes (within-gene range 0–1): IFNA7, IFNA10, IFNWP18.
- chr9:21,966,929–21,967,751, 1 gene (within-gene range 0–1): CDKN2A-DT.
- chr14:22,438,547–22,488,652, 21 genes (within-gene range 0–2): TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:39,886,861–39,892,895, 3 genes, copy number 8: RN7SL763P, SNORA70, CR769767.1.
- chr9:39,983,821–39,984,401, 1 gene, copy number 8: RPL7AP49.

Autosomal genes at a single copy (total copy number 1): 816. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
